Gene-level copy-number profile of tumor specimen TCGA-22-4605-01A from TCGA case TCGA-22-4605, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 78.4 years (28,623 days).
Specimen TCGA-22-4605-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.248f8f76-b82b-4d61-830f-b0c39eb74d69.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4605-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/026e0c89-ac07-4467-b69a-89d8516dd638

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,004; copy number 2: 12,666; copy number 3: 21,484; copy number 4: 16,764; copy number 5: 3,882; copy number 6: 3,245; copy number 7: 39; copy number 8: 729; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4605-01A-21D-2121-01): tumor purity 0.24, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 773 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr8:123,563,070–124,372,692, 18 genes, copy number 7–12: AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65.
- chr8:142,834,247–142,916,506, 1 gene, copy number 7 (within-gene range 5–7): GML.
- chr8:142,872,356–143,541,447, 25 genes, copy number 7 (within-gene range 3–7): CYP11B1, CYP11B2, LY6E-DT, CDC42P3, LY6E, C8orf31, AK3P2, AC083982.1, LY6L, LY6H, GPIHBP1, ZFP41, AC138696.1, GLI4, MINCR, ZNF696, AC138696.2, TOP1MT, RNU6-220P, RHPN1-AS1, RHPN1, AC105118.1, MAFA-AS1, MAFA, ZC3H3.
- chr20:603,797–1,329,139, 18 genes, copy number 8: TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2.
- chr20:1,320,710–1,324,367, 1 gene, copy number 8: AL136531.3.

Autosomal genes at a single copy (total copy number 1): 753. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
